Gene-level copy-number profile of tumor specimen TCGA-EJ-A46G-01A from TCGA case TCGA-EJ-A46G, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.8 years (26,219 days).
Specimen TCGA-EJ-A46G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.e96bec69-b10d-49e8-b180-6f1d782a2671.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-A46G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8343760f-8a25-4c5c-8cf0-3bbe4ad2b1ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,183; copy number 2: 43,425; copy number 3: 10,610; copy number 4: 1,662; copy number 5: 608; copy number 6: 145; copy number 7: 135; copy number 8: 12; copy number 9: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-A46G-01A-31D-A26L-01): tumor purity 0.8, ploidy 2.25, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 923 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:81,080,790–81,992,436, 14 genes, copy number 5 (within-gene range 3–5): MTND2P30, RPL7P10, AL357632.1, AC093154.1, RN7SKP247, ADGRL2, HNRNPA3P14, ARID3BP1, AL138799.1, AL138799.3, MED28P8, AC117944.1, AL138799.2, ST13P20.
- chr1:99,968,383–100,641,723, 28 genes, copy number 6: AC118553.1, SLC35A3, AC118553.2, RNU6-750P, RNU6-1318P, MFSD14A, AC093019.2, SASS6, AC093019.1, TRMT13, LRRC39, DBT, RPL23AP90, BRI3P1, AL445928.2, AL445928.1, RTCA-AS1, RTCA, MIR553, AC104457.1, AC104457.2, CDC14A, BCAS2P2, AL589990.1, GPR88, AC099670.1, LINC01349, AC099670.3.
- chr2:151,788,984–153,593,288, 27 genes, copy number 5 (within-gene range 2–5): ARL5A, AC097448.1, AC068547.1, CACNB4, AC079790.1, STAM2, RPL30P2, AC079790.2, Y_RNA, FMNL2, NUDCP1, AC012066.1, AC012443.1, AC012443.2, PRPF40A, ARL6IP6, AC009969.1, UBQLN4P2, ATP5PBP4, AC011901.1, AC079150.1, LINC01850, RPL23AP29, TUBAP13, AC012501.2, AC012501.1, RPRM.
- chr3:30,292,548–31,182,650, 11 genes, copy number 5: AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2, GADL1, MIR466, CNN2P6.
- chr3:164,001,606–164,686,076, 3 genes, copy number 5: AC084017.1, MIR1263, LINC01323.
- chr3:193,553,213–193,697,811, 5 genes, copy number 6 (within-gene range 3–6): ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA.
- chr5:160,563,120–161,549,044, 5 genes, copy number 5 (within-gene range 3–5): ATP10B, AC008456.1, AC011363.1, LINC02159, GABRB2.
- chr5:180,226,378–180,578,358, 8 genes, copy number 5 (within-gene range 3–5): AC104115.1, MAPK9, AC104115.2, AC008610.1, GFPT2, AC034213.1, RNU6-525P, CNOT6.
- chr6:96,648,489–96,837,477, 7 genes, copy number 5: RPS7P8, RNU4-70P, TYMSP1, AL355143.1, EEF1GP6, AL033379.1, GPR63.
- chr7:106,372,251–108,995,029, 44 genes, copy number 5 (within-gene range 2–5): AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1.
- chr8:89,243,401–91,219,236, 29 genes, copy number 6: RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661.
- chr8:98,024,851–98,294,393, 9 genes, copy number 5: RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P.
- chr8:125,091,679–127,636,867, 33 genes, copy number 5–7: NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1.
- chr8:133,325,997–133,571,940, 6 genes, copy number 5: KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3.
- chr9:92,456,205–92,539,184, 4 genes, copy number 5 (within-gene range 3–5): ASPN, ECM2, MIR4670, AL157827.1.
- chr9:93,451,685–95,087,159, 42 genes, copy number 6 (within-gene range 4–6): FAM120A, PHF2, MIR548AU, AL442224.1, MIR4291, BARX1, BARX1-DT, PTPDC1, CYCSP24, AL360020.1, AL158152.1, MIRLET7A1HG, MIRLET7A1, MIRLET7F1, LINC02603, MIRLET7D, ZNF169, VDAC1P11, NUTM2F, AL691447.2, AL691447.1, PTMAP12, MFSD14B, YRDCP1, AL358232.2, AL358232.1, RNU6-669P, PCAT7, FBP2, FBP1, AL157936.1, AOPEP, MIR2278, AL807757.1, AL807757.2, AL353768.1, AL353768.2, MIR6081, MIR23B, MIR27B, MIR3074, MIR24-1.
- chr9:95,113,708–95,142,541, 3 genes, copy number 6: AL354893.2, AL354893.1, RNA5SP288.
- chr9:110,599,475–110,806,558, 3 genes, copy number 5: AL592463.1, MUSK, AL513328.1.
- chr9:136,935,840–137,870,016, 67 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr10:113,588,714–114,232,304, 17 genes, copy number 5 (within-gene range 4–5): NRAP, CASP7, AL592546.2, PLEKHS1, MIR4483, AL592546.1, DCLRE1A, NHLRC2, AL592546.3, ADRB1, AC022023.2, RNU6-709P, UBE2V1P5, CCDC186, AC022023.1, MIR2110, TDRD1.
- chr11:66,744,451–66,843,516, 1 gene, copy number 8 (within-gene range 4–8): C11orf80.
- chr11:66,842,835–69,018,447, 98 genes, copy number 5–8 (broad region; genes not listed).
- chr11:123,188,802–124,582,942, 59 genes, copy number 5 (within-gene range 3–5): AP001970.1, U8, LINC02727, PHBP17, GRAMD1B, MIR4493, SF3A3P2, SCN3B, AP002765.1, ZNF202, OR6X1, RNU1-21P, OR6M1, OR6M2P, OR6M3P, TMEM225, OR8D4, OR4D5, OR6T1, OR10S1, OR10G6, OR10G5P, OR10G4, OR10G9, OR10G8, OR10G7, OR10D5P, OR10D4P, OR10N1P, VWA5A, OR10D1P, OR10D3, OR8F1P, OR8G3P, OR8G2P, OR8G7P, OR8G1, OR8G5, SLC5A4P1, OR8D1, OR8D2, OR8B7P, OR8B6P, OR8B5P, OR8B1P, OR8C1P, OR8B2, OR8B3, OR8X1P, AP001804.1, OR8B4, OR8B8, OR8A2P, OR8B9P, OR8B10P, OR8A3P, AP000916.1, OR8B12, OR8A1.
- chr14:33,924,227–34,462,774, 1 gene, copy number 5 (within-gene range 2–5): EGLN3.
- chr14:34,416,687–38,202,923, 92 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr14:60,091,911–60,299,087, 7 genes, copy number 5 (within-gene range 3–5): PCNX4, DHRS7, SCOCP1, PSMA3P1, RPL17P2, AL157756.1, PPM1A.
- chr17:59,893,046–63,521,848, 113 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr18:12,984,694–14,252,140, 40 genes, copy number 5 (within-gene range 2–5): AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2, AP001198.1, LDLRAD4, AP002505.1, C18orf15, AP002505.3, AP002505.2, AP002439.1, LDLRAD4-AS1, MIR5190, AP005131.5, AP005131.4, AP005131.2, AP005131.1, AP005131.3, MIR4526, AP001010.1, FAM210A, AP001525.1, RN7SL362P, RNMT, MC5R, MC2R, AP001086.1, AC006557.6, AC006557.5, ZNF519, AC006557.4, AC006557.1, AC006557.3, FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1.
- chr18:58,018,794–60,654,623, 64 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr19:51,745,172–52,139,938, 22 genes, copy number 5 (within-gene range 3–5): FPR1, FPR2, AC018755.5, FPR3, ZNF577, AC006272.1, AC006272.2, AC074141.1, ZNF649-AS1, ZNF649, AC011460.1, ZNF613, ZNF350-AS1, ZNF350, ZNF615, ZNF614, ZNF432, AC011468.5, AC011468.1, ZNF841, AC011468.4, ZNF616.
- chr19:55,528,611–56,504,362, 61 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 960. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
